HCMI case HCM-CSHL-0623-C18 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6382c82d-dffb-4f43-8fb2-1d0ec187363e

Demographics
Sex at birth: male; Year of birth: 1970; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.4; Tissue or organ of origin: Colon, NOS; Classification of tumor: primary; Age at diagnosis: 47.6 years (17,397 days); AJCC staging edition: 8th; AJCC pathologic T: T3; AJCC pathologic N: N2a; AJCC pathologic M: M1a; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Liver.
   Pathology details: Lymphatic invasion present: Yes; Perineural invasion present: No; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine + Oxaliplatin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 32 days; Days to treatment end: 196 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cetuximab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 237 days; Days to treatment end: 285 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan + Leucovorin Calcium; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: FOLFIRI; Days to treatment start: 237 days; Days to treatment end: 285 days.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 404 days (1.1 years).
   Treatment given: Treatment type: Radiation, Stereotactic/Gamma Knife/SRS; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 438 days (1.2 years); Days to treatment end: 561 days (1.5 years).
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.
2. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; ICD-10 code: C78.7; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Liver; Classification of tumor: metastasis; Age at diagnosis: 47.6 years (17,397 days).
   Pathology details: Lymphatic invasion present: Yes; Perineural invasion present: No; Vascular invasion present: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Capecitabine; Treatment intent type: Maintenance Therapy; Regimen or line of therapy: XELOX; Days to treatment start: 214 days; Days to treatment end: 283 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cetuximab; Treatment intent type: Maintenance Therapy; Days to treatment start: 214 days; Days to treatment end: 283 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Fluorouracil + Irinotecan + Leucovorin Calcium; Treatment intent type: Maintenance Therapy; Regimen or line of therapy: FOLFIRI; Days to treatment start: 214 days; Days to treatment end: 283 days; Treatment outcome: Progressive Disease.

Follow-up (3 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to progression: 0 days.
- Days to follow up: 992 days (2.7 years); Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 677.

Molecular and laboratory tests
- BRAF mutation, nos: Negative.
- KRAS mutation, nos: Negative.
- Test (Microsatellite Analysis): Negative.
- Test (Microsatellite Analysis): Negative; Loci count: 5.
- Test: Negative; Mismatch repair mutation: Yes.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.
- Timepoint category: Initial Diagnosis; Weight: 75 kg; Height: 182 cm; BMI: 23.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Colorectal Cancer.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0623-C18-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0623-C18-11A-01-S2-HE: Section location: Bottom; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 90; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.
  Slide HCM-CSHL-0623-C18-11A-01-S1-HE: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 90; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 2.
- Sample HCM-CSHL-0623-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
